Somatic mutation profile of tumor specimen 0DEAZ5 from CCDI case PBBPRU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.3 years (462 days).
Specimen 0DEAZ5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fbda8bd-5a5c-49fc-a9c3-3ee6ad199151.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEAYU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9f410b5-02f7-4822-9163-db835e3ce66a

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, RNA 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL1RAPL2 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 220/481 reads (46%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.77); catalogued as rs751827217, COSV61155639, COSV61168151; called by muse, mutect2, varscan2
- MACF1 | c.20518G>A p.D6840N (on ENST00000372915; = p.D4885N on NM_012090.5) | Missense Mutation (SNP) | VAF 50/1054 reads (5%) | catalogued as rs769550602, COSV57129886, COSV57137881; called by muse, mutect2
- GRIK5 | c.2815_2846del p.I939Afs*184 | Frame Shift Del (DEL) | VAF 176/450 reads (39%) | called by mutect2, varscan2
- TRAPPC10 | c.2850C>A p.S950R | Missense Mutation (SNP) | VAF 194/1297 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LUZP1 | c.2430G>A p.P810= | Silent (SNP) | VAF 103/573 reads (18%) | catalogued as rs376596340, COSV100034783; called by muse, mutect2, varscan2
- MYORG | c.795G>A p.T265= | Silent (SNP) | VAF 249/541 reads (46%) | catalogued as rs1193784865, COSV52626390; called by muse, mutect2, varscan2
- AL589987.1 | n.217G>T | RNA (SNP) | VAF 210/567 reads (37%) | called by muse, mutect2, varscan2
- AL589987.1 | n.218A>T | RNA (SNP) | VAF 209/565 reads (37%) | called by muse, mutect2, varscan2
- FEZF2 | c.*78A>G | 3'UTR (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
